Somatic mutation profile of tumor specimen TARGET-50-PAJNNR-01A (aliquot TARGET-50-PAJNNR-01A-01D) from TARGET case TARGET-50-PAJNNR, project TARGET-WT (High-Risk Wilms Tumor). Sex at birth: male; Vital status: Dead; Primary diagnosis: Wilms tumor; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 6.2 years (2,265 days).
Specimen TARGET-50-PAJNNR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bbf20edb-8d26-4ad7-b95e-95d65e863c26.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-50-PAJNNR-10A (Blood Derived Normal), aliquot TARGET-50-PAJNNR-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c8001382-a678-4eef-ad62-e943c1df15d3

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 1, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.1025G>C p.R342P | Missense Mutation (SNP) | VAF 37/41 reads (90%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as rs375338359, CM098494, COSV52690857, COSV52980226, COSV53438718; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CSMD2 | c.9559C>T p.P3187S | Missense Mutation (SNP) | VAF 104/211 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.164); catalogued as rs777894161, COSV53931985; called by muse, mutect2, varscan2
- LRRC4 | c.243C>G p.N81K | Missense Mutation (SNP) | VAF 188/435 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV50815553; called by muse, mutect2, varscan2
- NAALAD2 | c.1369A>G p.T457A | Missense Mutation (SNP) | VAF 127/477 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.096); catalogued as COSV58963248, COSV58964158; called by muse, mutect2, varscan2
- NLGN4X | c.445T>G p.L149V | Missense Mutation (SNP) | VAF 163/173 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV52026784; called by muse, mutect2, varscan2
- RYR2 | c.14347G>C p.V4783L | Missense Mutation (SNP) | VAF 280/655 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV63697699; called by muse, mutect2, varscan2
- ACTB | c.846_848del p.I282del | In Frame Del (DEL) | VAF 43/106 reads (41%) | called by pindel, varscan2
- PTPN23 | c.2028G>A p.R676= | Silent (SNP) | VAF 39/71 reads (55%) | called by muse, mutect2, varscan2
- PUS1 | c.*19C>T | 3'UTR (SNP) | VAF 16/41 reads (39%) | called by muse, mutect2, varscan2
